Gene-level copy-number profile of tumor specimen TCGA-VS-A9UY-01A from TCGA case TCGA-VS-A9UY, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 29.3 years (10,707 days).
Specimen TCGA-VS-A9UY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.2957b88d-c280-441e-975d-01317f3931f7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VS-A9UY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/59c3b03f-1c5f-4017-86ee-f3e7dea1585b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 4,958; copy number 2: 49,025; copy number 3: 3,146; copy number 4: 2,420; copy number 5: 29; copy number 6: 181; copy number 7: 28; copy number 11: 4; copy number 14: 6; copy number 23: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VS-A9UY-01A-11D-A42N-01): tumor purity 0.84, ploidy 2.06, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,992,543–140,992,659, 1 gene: Y_RNA.
- chr2:141,208,082–141,208,376, 1 gene: RPS16P3.
- chr16:78,273,497–78,355,834, 2 genes: AC106743.1, LSM3P5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 265 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:31,114,750–31,140,092, 1 gene, copy number 6 (within-gene range 4–6): PSORS1C1.
- chr6:31,137,534–32,195,523, 136 genes, copy number 6 (broad region; genes not listed).
- chr7:54,185,071–55,646,951, 27 genes, copy number 11–23: AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6.
- chr11:69,641,156–71,928,654, 72 genes, copy number 6–7 (within-gene range 2–7) (broad region; genes not listed).
- chr11:128,458,761–130,041,071, 29 genes, copy number 5 (within-gene range 3–5): ETS1, MIR6090, ETS1-AS1, AP001122.1, FLI1, SENCR, KCNJ1, AP000920.1, KCNJ5, C11orf45, TP53AIP1, ARHGAP32, RNU6-876P, Y_RNA, RNU6-874P, ZNF123P, BARX2, RPS27P20, AP003500.1, LINC01395, AP003327.2, AP003327.1, TMEM45B, NFRKB, PRDM10, LINC00167, AP003041.1, ELOBP2, AP003041.2.

Autosomal genes at a single copy (total copy number 1): 4,958. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
